Somatic mutation profile of tumor specimen TCGA-D8-A27E-01A (aliquot TCGA-D8-A27E-01A-11D-A16D-09) from TCGA case TCGA-D8-A27E, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 66.6 years (24,315 days).
Specimen TCGA-D8-A27E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b28e68c0-bada-495f-a4d5-93a42848605f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A27E-10A (Blood Derived Normal), aliquot TCGA-D8-A27E-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce9f684d-73e7-45b1-bd2a-86f9da1b3447

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Del 2, Silent 1, RNA 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASZ1 | c.821C>G p.T274R | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV52911427; called by muse, mutect2, varscan2
- CDK10 | c.995C>A p.P332Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV57045938; called by muse, mutect2, varscan2
- CEACAM19 | c.118C>G p.P40A | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62551838; called by muse, mutect2, varscan2
- COL6A6 | c.6584G>A p.R2195Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs544399652, COSV62018767; called by muse, mutect2, varscan2
- MAPK14 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768171262, COSV57694769; called by muse, mutect2, varscan2
- MYO5B | c.1556G>T p.G519V | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53212058, COSV53212241; called by muse, mutect2, varscan2
- OTUD4 | c.3025G>A p.A1009T (on ENST00000447906 / NM_001366057.1; = p.A944T on NM_001102653.1) | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as COSV71381504; called by muse, mutect2, varscan2
- PCED1A | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs756545276, COSV62313306; called by muse, mutect2, varscan2
- GLI3 | c.1539_1554del p.F513Lfs*17 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- MZF1 | c.1820_1831dup p.S607_L610dup | In Frame Ins (INS) | VAF 14/29 reads (48%) | called by mutect2, varscan2
- TBC1D17 | c.472del p.R158Afs*73 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- SERPINA9 | c.279G>A p.Q93= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV100098738; called by muse, mutect2
- MIR516B1 | n.29A>C | RNA (SNP) | VAF 52/147 reads (35%) | catalogued as rs367758249; called by muse, mutect2, varscan2
- RPL3 | c.688+88_688+95del | Intron (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel
